Gene-level copy-number profile of tumor specimen ALCH-ADWB-TTP1-A from ALCHEMIST case ALCH-ADWB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Non-small cell carcinoma; Age at diagnosis: 53.2 years (19,430 days).
Specimen ALCH-ADWB-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d9d31404-b91f-4f05-974d-fd6a12ac8cd8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADWB-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,242 have no estimate.
https://portal.gdc.cancer.gov/files/2e5dcef1-7ea4-4824-b640-25ea4b250cae

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 104; copy number 1: 4,614; copy number 2: 53,046; copy number 3: 595; copy number 4: 11; copy number 5: 8; copy number 6: 3.

Homozygous deletions (total copy number 0; autosomes only): 102 genes in 36 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:28,544,460–28,578,545, 2 genes (within-gene range 0–1): AL513497.1, TRNAU1AP.
- chr1:200,008,505–200,014,795, 2 genes: RNU6-716P, RNU6-609P.
- chr2:90,159,840–90,160,335, 1 gene (within-gene range 0–1): IGKV1D-12.
- chr2:90,359,809–91,621,421, 5 genes (within-gene range 0–1): AC233263.1, AC233263.7, AC233266.1, AC233266.2, AC116050.1.
- chr2:131,491,160–131,521,573, 2 genes (within-gene range 0–2): MIR4784, SMPD4BP.
- chr2:203,238,977–203,306,026, 2 genes: CYP20A1, RN7SL670P.
- chr2:219,482,073–219,516,877, 5 genes (within-gene range 0–2): ASIC4-AS1, AC053503.6, SPEGNB, AC053503.4, GMPPA.
- chr2:219,569,162–219,575,711, 1 gene (within-gene range 0–1): INHA.
- chr2:232,368,576–232,382,889, 3 genes: AC068134.3, ALPP, AC068134.1.
- chr2:232,456,125–232,460,753, 1 gene: ALPI.
- chr2:232,520,388–232,536,667, 2 genes: PRSS56, CHRND.
- chr4:165,053,864–165,060,554, 1 gene: TRIM75P.
- chr5:80,288,449–80,365,832, 9 genes: KRT18P45, AC026410.1, AC026410.4, AC026410.2, SPZ1, RBMX2P5, AC026410.3, HNRNPA1P12, RNU6-211P.
- chr5:126,751,963–126,776,486, 2 genes: LMNB1-DT, RNU6-752P.
- chr5:181,306,502–181,324,685, 1 gene: AC138035.1.
- chr6:73,413,515–73,525,587, 3 genes (within-gene range 0–2): CGAS, RNU6-975P, EEF1A1.
- chr7:6,923,804–6,930,835, 2 genes: ALG1L5P, AC079804.1.
- chr7:57,822,201–57,822,942, 2 genes: AC023141.10, AC023141.6.
- chr7:76,959,835–77,043,775, 1 gene (within-gene range 0–3): DTX2P1-UPK3BP1-PMS2P11.
- chr7:76,972,679–77,032,361, 6 genes (within-gene range 0–2): AC114737.1, DTX2P1, UPK3BP1, PMS2P11, Y_RNA, SPDYE17.
- chr7:149,191,043–149,191,223, 1 gene: AC004890.1.
- chr9:124,777,133–124,814,885, 1 gene: OLFML2A.
- chr10:133,344,643–133,350,726, 2 genes (within-gene range 0–2): BANF1P2, AL360181.1.
- chr10:133,355,158–133,358,025, 1 gene: FUOM.
- chr15:25,174,927–25,203,308, 16 genes (within-gene range 0–2): SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18.
- chr15:25,209,918–25,211,877, 2 genes (within-gene range 0–2): SNORD115-22, SNORD115-23.
- chr15:25,237,986–25,250,940, 8 genes (within-gene range 0–2): SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr15:65,442,463–65,517,704, 4 genes (within-gene range 0–2): DPP8, AC105129.3, AC105129.1, Y_RNA.
- chr16:58,665,109–58,684,770, 1 gene: SLC38A7.
- chr16:81,106,533–81,106,639, 1 gene (within-gene range 0–2): RNU6-1191P.
- chr17:2,712,309–2,723,947, 2 genes: AC005696.1, AC005696.4.
- chr17:2,755,705–3,037,741, 2 genes (within-gene range 0–1): RAP1GAP2, AC015921.1.
- chr19:41,169,861–41,170,166, 1 gene: RPL36P16.
- chr19:56,176,008–56,197,920, 2 genes: GALP, ZSCAN5B.
- chr20:31,563,166–31,581,214, 4 genes (within-gene range 0–1): HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P.
- chr22:35,717,872–35,729,483, 1 gene: APOL5.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:23,019,443–23,088,058, 4 genes, copy number 5 (within-gene range 1–5): KDM1A, AL031428.1, MIR3115, AL031428.2.
- chr13:112,313,467–112,321,758, 1 gene, copy number 5: LINC01043.
- chr17:36,183,235–36,196,758, 2 genes, copy number 5 (within-gene range 2–5): AC243829.1, CCL3L3.
- chr22:35,703,803–35,704,176, 1 gene, copy number 5: MRPS16P3.

Autosomal genes at a single copy (total copy number 1): 4,394. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
